Gene-level copy-number profile of tumor specimen TCGA-IE-A4EH-01A from TCGA case TCGA-IE-A4EH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Corpus uteri; Age at diagnosis: 35.2 years (12,871 days).
Specimen TCGA-IE-A4EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6d4f7b42-0796-4be3-8eda-0a866e282e1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IE-A4EH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33992d4d-c7ce-46eb-9c77-ef3ffec0efed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 145; copy number 1: 14,883; copy number 2: 39,908; copy number 3: 4,875.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IE-A4EH-01A-11D-A24M-01): tumor purity 0.92, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 145 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:237,966,827–238,457,520, 20 genes: UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2.
- chr4:49,096–202,303, 5 genes (within-gene range 0–1): BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2.
- chr10:75,431,624–76,560,168, 1 gene (within-gene range 0–1): LRMDA.
- chr10:75,592,644–77,638,369, 14 genes (within-gene range 0–1): AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1.
- chr13:48,488,963–51,080,862, 57 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B, GUCY1B2, RNA5SP29.
- chr16:34,962,970–35,522,465, 48 genes: AC135776.5, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3, VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
